TCGA case TCGA-DK-A3IK — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3f0a0748-9acc-4d0b-ba18-7c08bd183f86

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 87 years; Vital status: Dead; Days to death: 146 days.

Diagnoses (1)
1. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.2; Tissue or organ of origin: Lateral wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 87.8 years (32,076 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: Yes; Lymph nodes positive: 8; Lymph nodes tested: 27; Lymphatic invasion present: Yes; Vascular invasion present: Yes.

Follow-up (2 entries)
- Days to follow up: 67 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: day 146.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 91.2 kg; Height: 185 cm; BMI: 26.6.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DK-A3IK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 720 mg.
  Slide TCGA-DK-A3IK-01A-03-TSC: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DK-A3IK-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DK-A3IK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Papillary; Anatomic organ subdivision: Wall Lateral; Method initial path diagnosis: Endoscopic Biopsy; Lymph nodes examined: Yes; Lymphovascular invasion: Yes; Incidental prostate cancer indicator: No.
- Metastatic site list: Metastasis site: Lymph node only.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 146 days; disease-specific survival: no event (censored), 146 days; progression-free interval: no event (censored), 146 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DK-A3IK-01A-32D-A219-01): tumor purity 0.5, ploidy 2.97, whole-genome doublings 1.
